FM case AD14632 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts.
https://portal.gdc.cancer.gov/cases/507f60fb-8725-4e83-8684-3f0860d3e5c0

Female, 54.3 years: Hepatocellular carcinoma, NOS (ICD-O-3 8170/3) of the liver; metastasis biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
